Gene-level copy-number profile of tumor specimen TCGA-FS-A4F8-06A from TCGA case TCGA-FS-A4F8, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 65.8 years (24,023 days).
Specimen TCGA-FS-A4F8-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.064a5ad2-f38e-422e-8404-33a916595658.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FS-A4F8-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e6e8206a-9152-490e-9d01-f83d18f25467

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 2,221; copy number 2: 35,349; copy number 3: 16,321; copy number 4: 4,619; copy number 5: 337; copy number 6: 744; copy number 7: 164; copy number 10: 33.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FS-A4F8-06A-11D-A25P-01): tumor purity 0.37, ploidy 1.44, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:13,105,706–13,279,692, 1 gene (within-gene range 0–4): MPDZ.
- chr9:14,737,152–14,910,995, 1 gene (within-gene range 0–4): FREM1.
- chr9:14,850,429–15,362,134, 8 genes: RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B, RPL7P33.
- chr9:21,802,636–22,455,740, 16 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,278 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:122,152,333–190,092,279, 896 genes, copy number 6–7 (broad region; genes not listed).
- chr6:63,719,980–65,707,226, 1 gene, copy number 5 (within-gene range 4–5): EYS.
- chr6:64,377,795–77,097,788, 144 genes, copy number 5–10 (within-gene range 2–10) (broad region; genes not listed).
- chr8:62,110,524–69,834,978, 110 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr9:22,646,200–29,318,952, 59 genes, copy number 5–6: LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1.
- chr20:21,705,659–24,318,086, 68 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,221. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
